Somatic mutation profile of tumor specimen TCGA-AF-2691-01A (aliquot TCGA-AF-2691-01A-01D-1989-10) from TCGA case TCGA-AF-2691, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage I; Age at diagnosis: 48.6 years (17,759 days).
Specimen TCGA-AF-2691-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a6d50a1-2e1b-4980-855c-c6a27f3490cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AF-2691-10A (Blood Derived Normal), aliquot TCGA-AF-2691-10A-01D-1989-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23c82ea3-2796-4232-9b57-260316662748

The open-access MAF lists 37 somatic variants for this specimen: 30 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 6, Nonsense Mutation 2, Splice Site 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC1 | c.1851G>C p.R617S | Missense Mutation (SNP) | VAF 43/325 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.949); catalogued as COSV100579430; called by muse, mutect2, varscan2
- CDK10 | c.335+1G>T p.X112_splice (on ENST00000353379 / NM_052988.5; = p.X41_splice on NM_052987.4) | Splice Site (SNP) | VAF 48/260 reads (18%) | catalogued as COSV99232252; called by muse, mutect2, varscan2
- GPR50 | c.1768C>A p.P590T | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV54441369; called by muse, mutect2, varscan2
- OVOL1 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.068); catalogued as rs1205506450, COSV100256826; called by muse, mutect2, varscan2
- PANK4 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 41/241 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs762410583, COSV65868123; called by muse, mutect2, varscan2
- RIPOR3 | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1199554662, COSV50387865, COSV50404238; called by muse, mutect2
- SNAPC4 | c.2008C>T p.P670S | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as rs1473772399; called by muse, mutect2, varscan2
- TRPM1 | c.4550G>A p.R1517Q | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs543202406; called by muse, mutect2, varscan2
- WDPCP | c.1436-2A>T p.X479_splice | Splice Site (SNP) | VAF 26/104 reads (25%) | catalogued as COSV99705019; called by muse, mutect2, varscan2
- ADAMTS8 | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 36/191 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APLP1 | c.1889A>T p.Q630L (on ENST00000221891 / NM_001024807.3; = p.Q629L on NM_005166.4) | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- CD248 | c.2201G>A p.S734N | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- CENPT | c.685A>G p.T229A | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL24A1 | c.3031G>T p.G1011* | Nonsense Mutation (SNP) | VAF 53/213 reads (25%) | called by muse, mutect2, varscan2
- EPHA2 | c.2294A>G p.E765G | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FAM83E | c.675C>A p.S225R | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FAM83H | c.641C>G p.P214R | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- FOXK2 | c.1297C>T p.Q433* | Nonsense Mutation (SNP) | VAF 26/209 reads (12%) | called by muse, mutect2, varscan2
- GPR37 | c.902C>A p.A301D | Missense Mutation (SNP) | VAF 78/293 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HYAL2 | c.404A>C p.E135A | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ITPKB | c.1592C>T p.T531I | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAMA5 | c.5665G>T p.G1889W | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEFM | c.974A>G p.Q325R | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- PNCK | c.833G>T p.R278M (on ENST00000340888 / NM_001366975.1; = p.R361M on NM_001039582.3) | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- PTPRT | c.2600C>A p.P867H | Missense Mutation (SNP) | VAF 40/396 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PTPRT | c.2599C>A p.P867T | Missense Mutation (SNP) | VAF 40/400 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2
- RIMBP2 | c.1558A>G p.N520D | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- SPZ1 | c.653A>G p.K218R | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TCTN1 | c.821G>T p.R274M | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); called by muse, mutect2
- TCTN1 | c.1364C>T p.A455V (on ENST00000551590 / NM_001173975.3; = p.A441V on NM_024549.6) | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- COL25A1 | c.267G>T p.V89= | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as rs1194710696; called by muse, mutect2, varscan2
- COL6A1 | c.1416C>T p.I472= | Silent (SNP) | VAF 30/162 reads (19%) | catalogued as rs761232584; called by muse, mutect2, varscan2
- FAM184A | c.2811G>A p.L937= | Silent (SNP) | VAF 28/213 reads (13%) | catalogued as rs570479498, COSV100137717; called by muse, mutect2, varscan2
- FOSL1 | c.306G>A p.P102= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as rs767082299; called by muse, varscan2
- FRY | c.8262T>A p.P2754= | Silent (SNP) | VAF 196/546 reads (36%) | called by muse, mutect2, varscan2
- REM1 | c.717G>T p.V239= | Silent (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2
- HSPA12A | c.*2C>T | 3'UTR (SNP) | VAF 11/72 reads (15%) | catalogued as rs781848826, COSV100979791; called by muse, mutect2, varscan2
